Somatic mutation profile of tumor specimen TCGA-3A-A9IZ-01A (aliquot TCGA-3A-A9IZ-01A-12D-A40W-08) from TCGA case TCGA-3A-A9IZ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 47.3 years (17,294 days).
Specimen TCGA-3A-A9IZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65b65bac-d06f-4b54-8733-ad60f19565c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IZ-10A (Blood Derived Normal), aliquot TCGA-3A-A9IZ-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63e5cf9c-3fa8-4c17-bc2e-efbde8af2c1d

The open-access MAF lists 64 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Frame Shift Del 4, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 66/243 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 79/215 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 118/419 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as rs763890617, COSV99200985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATAD2B | c.1814G>A p.C605Y | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99477192; called by muse, mutect2, varscan2
- BMERB1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 54/642 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100252756, COSV55510581; called by muse, mutect2
- CDR2 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 124/525 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.943); catalogued as COSV51675644, COSV99193489; called by muse, mutect2, varscan2
- CREB5 | c.419C>A p.S140Y (on ENST00000357727 / NM_182898.4; = p.S133Y on NM_004904.3) | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100744363; called by muse, mutect2, varscan2
- CSMD2 | c.790T>A p.S264T | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.464); catalogued as COSV99587360; called by muse, mutect2, varscan2
- CYP1A1 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 135/548 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as rs1167913201, COSV65697827; called by muse, mutect2, varscan2
- DNMT3A | c.1550G>C p.C517S | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99260613; called by muse, mutect2, varscan2
- DOCK2 | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs754028409, COSV56961008; called by muse, mutect2, varscan2
- DSG2 | c.1496T>G p.L499R | Missense Mutation (SNP) | VAF 19/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99852929; called by muse, mutect2
- ERI1 | c.640A>T p.M214L | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV99141295; called by muse, mutect2, varscan2
- FBN1 | c.4181G>C p.G1394A | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100354228, COSV57312093; called by muse, mutect2, varscan2
- FLG | c.11720G>A p.R3907H | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs554551056, COSV64242250; called by muse, mutect2
- FLG | c.5184G>T p.E1728D | Missense Mutation (SNP) | VAF 375/1342 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754233043, COSV100911186, COSV64238059; called by muse, mutect2, varscan2
- FNDC3B | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 33/940 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100393814, COSV61049434; called by muse, mutect2
- GALNT16 | c.430A>T p.K144* | Nonsense Mutation (SNP) | VAF 53/179 reads (30%) | catalogued as COSV100545821; called by muse, mutect2, varscan2
- GALNT5 | c.2347C>G p.L783V | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1483825460, COSV99374957; called by muse, mutect2, varscan2
- HAGH | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.399); catalogued as rs1163436710, COSV101272429; called by muse, mutect2, varscan2
- HCN1 | c.2606G>A p.R869K | Missense Mutation (SNP) | VAF 188/616 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs372807250, COSV57543772; called by muse, mutect2, varscan2
- KCNA4 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068715; called by muse, mutect2
- KIAA0319 | c.1116G>A p.W372* | Nonsense Mutation (SNP) | VAF 148/546 reads (27%) | catalogued as COSV100985334; called by muse, mutect2, varscan2
- KMT2A | c.8677C>A p.L2893I | Missense Mutation (SNP) | VAF 277/1275 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100628291; called by muse, mutect2, varscan2
- MYH15 | c.3371A>C p.Q1124P | Missense Mutation (SNP) | VAF 91/315 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842652; called by muse, mutect2, varscan2
- NOTCH1 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 81/337 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.182); catalogued as rs761629787, COSV99486230; called by muse, mutect2, varscan2
- OR51A7 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 150/378 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs951186127, COSV63788783; called by muse, mutect2, varscan2
- OR9Q2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 86/405 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs1565101755, COSV61112280; called by muse, mutect2, varscan2
- OXR1 | c.593G>A p.R198Q (on ENST00000442977 / NM_001198532.1; = p.R197Q on NM_018002.3) | Missense Mutation (SNP) | VAF 99/489 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs778365533, COSV100366964; called by muse, mutect2, varscan2
- PALD1 | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 32/135 reads (24%) | catalogued as COSV99698087; called by muse, mutect2, varscan2
- PANX1 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 96/434 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.061); catalogued as rs543769570, COSV57133549, COSV99921869; called by muse, mutect2, varscan2
- PCDHGB7 | c.1640G>C p.S547T | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.268); catalogued as COSV99533651; called by muse, mutect2, varscan2
- PFAS | c.2857G>A p.V953M | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs561030492, COSV100118827; called by muse, mutect2, varscan2
- PKD1L2 | c.1262G>C p.G421A | Missense Mutation (SNP) | VAF 138/613 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV100449694, COSV61417947; called by muse, mutect2, varscan2
- POTEE | c.857A>C p.Q286P | Missense Mutation (SNP) | VAF 48/1112 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100387323; called by muse, mutect2
- PPP1R3A | c.3094G>C p.V1032L | Missense Mutation (SNP) | VAF 174/699 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99492290; called by muse, mutect2, varscan2
- PTDSS1 | c.1226A>G p.Y409C | Missense Mutation (SNP) | VAF 58/338 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs756721220, COSV100428530; called by muse, mutect2, varscan2
- SLC12A2 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 103/432 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs373411636, COSV52477470; called by muse, mutect2, varscan2
- SLC15A1 | c.1685A>G p.N562S | Missense Mutation (SNP) | VAF 102/264 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100919442; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.992A>G p.E331G | Missense Mutation (SNP) | VAF 74/292 reads (25%) | PolyPhen benign (0.046); catalogued as COSV100602506; called by muse, mutect2, varscan2
- ZNF215 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs761961443, COSV99549370; called by muse, mutect2, varscan2
- ABCC6 | c.1587_1588dup p.L530Pfs*34 | Frame Shift Ins (INS) | VAF 73/420 reads (17%) | called by mutect2, pindel, varscan2
- ARMH3 | c.246C>G p.F82L | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.127); called by muse, mutect2
- ATRNL1 | c.3342_3349del p.Q1115Lfs*8 | Frame Shift Del (DEL) | VAF 76/303 reads (25%) | called by mutect2, pindel, varscan2
- FER1L5 | c.4895_4917del p.P1632Lfs*15 (on ENST00000623019; = p.P1605Lfs*15 on NM_001293083.2) | Frame Shift Del (DEL) | VAF 68/388 reads (18%) | called by mutect2, pindel
- SESN1 | c.1310_1335del p.I437Kfs*8 (on ENST00000356644 / NM_001199933.1; = p.I496Kfs*8 on NM_014454.3) | Frame Shift Del (DEL) | VAF 54/131 reads (41%) | called by mutect2, pindel
- SLC6A3 | c.579del p.P194Lfs*66 | Frame Shift Del (DEL) | VAF 64/422 reads (15%) | called by mutect2, pindel, varscan2
- ARHGAP19 | c.387T>A p.I129= | Silent (SNP) | VAF 78/202 reads (39%) | catalogued as COSV100363048; called by muse, mutect2, varscan2
- EPS8 | c.1116A>C p.T372= | Silent (SNP) | VAF 21/379 reads (6%) | catalogued as COSV99842811; called by muse, mutect2
- PNMA5 | c.810G>C p.L270= | Silent (SNP) | VAF 53/295 reads (18%) | catalogued as COSV100721603; called by muse, mutect2, varscan2
- POTEH | c.261C>T p.D87= | Silent (SNP) | VAF 248/1484 reads (17%) | catalogued as rs532473477, COSV100624818, COSV58883613; called by muse, varscan2
- PPP3R2 | c.186C>T p.F62= | Silent (SNP) | VAF 101/378 reads (27%) | catalogued as rs868308424, COSV62452567; called by muse, mutect2, varscan2
- PRMT8 | c.159C>A p.P53= | Silent (SNP) | VAF 284/1038 reads (27%) | catalogued as COSV99713259; called by muse, mutect2, varscan2
- PRUNE2 | c.7803C>T p.A2601= | Silent (SNP) | VAF 82/326 reads (25%) | catalogued as COSV100944323; called by muse, mutect2, varscan2
- SDK2 | c.4557A>T p.L1519= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV101167137; called by muse, mutect2, varscan2
- SLC4A1 | c.777G>A p.P259= | Silent (SNP) | VAF 73/243 reads (30%) | catalogued as rs754558070, COSV52259398, COSV99293102; called by muse, mutect2, varscan2
- SPATA31E1 | c.1677C>T p.V559= | Silent (SNP) | VAF 32/917 reads (3%) | catalogued as COSV100350104; called by muse, mutect2
- STON1 | c.708C>T p.L236= | Silent (SNP) | VAF 49/512 reads (10%) | catalogued as COSV100561614; called by muse, mutect2, varscan2
- VAV1 | c.1320C>G p.S440= | Silent (SNP) | VAF 26/332 reads (8%) | catalogued as COSV100408745, COSV58385089; called by muse, mutect2
- WDR33 | c.2979C>T p.G993= | Silent (SNP) | VAF 20/624 reads (3%) | catalogued as COSV100459730; called by muse, mutect2
- XPC | c.459C>T p.F153= | Silent (SNP) | VAF 50/232 reads (22%) | catalogued as COSV99542141; called by muse, mutect2, varscan2
- ZSCAN20 | c.1257T>C p.D419= | Silent (SNP) | VAF 56/219 reads (26%) | catalogued as COSV100792518; called by muse, mutect2, varscan2
- ADGRL2 | c.3625+303T>C | Intron (SNP) | VAF 53/195 reads (27%) | catalogued as COSV99587700; called by muse, mutect2, varscan2
- MIR19B2 | n.33G>A | RNA (SNP) | VAF 62/385 reads (16%) | called by muse, mutect2, varscan2
